Gene-level copy-number profile of tumor specimen TCGA-VD-AA8O-01A from TCGA case TCGA-VD-AA8O, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 77.3 years (28,250 days).
Specimen TCGA-VD-AA8O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.24629620-453e-4a87-b1f5-d5009bedcc8f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VD-AA8O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-VD-AA8O-01A|TCGA-VD-AA8O-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6f479620-9142-42da-a48b-7dd28ded6a40

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 2,388; copy number 2: 19,849; copy number 3: 21,939; copy number 4: 15,398; copy number 5: 236.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VD-AA8O-01A-11D-A39V-01): tumor purity 0.9, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,556,069–11,771,350, 1 gene (within-gene range 0–2): VGLL4.
- chr3:52,254,434–52,400,491, 7 genes (within-gene range 0–2): WDR82, MIRLET7G, GLYCTK, GLYCTK-AS1, MIR135A1, DNAH1, PPP2R5CP.
- chr3:65,687,301–65,688,468, 1 gene: ILF2P1.
- chr3:67,225,464–67,225,527, 1 gene: MIR4272.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
